Surgical pathology report (de-identified scan), TCGA case TCGA-CS-5390, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-5390-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right parietal lobe brain tumor: oligodendroglioma, see comment, see microscopic description.
2. Specimen not received:
3. Right parietal lobe brain tumor: oligodendroglioma, see comment, see microscopic description.

Comment:

While the tumor is best classified as Oligodendroglioma, WHO grade (II), the identification of multiple mitotic figures on slide 3A and a MIB-1 (Ki67) proliferation index of greater than 10% suggests that this tumor may have a growth potential greater than that of a grade II oligodendroglioma. Clinical correlation recommended.

Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor is a moderately cellular oligodendroglioma composed of cells with ovoid to round nuclei infiltrating gray and white matter. Prominent perineuronal satellitosis is present. Many tumor cells have perinuclear halos (slide 1B). Scattered mitotic figures are identified (slide 3A). Neither necrosis nor microvascular are identified. The proliferation index, as determined by nuclear staining with the immunohistochemical Ki67 (MIB-1) is focally greater than 10% (slide 3A). Based on histologic appearance, this tumor is best classified as oligodendroglioma, WHO grade II. The elevated proliferation index and mitotic figures suggest however that this tumor may have a growth

[page 2 of 3]
potential greater than a grade II oligodendroglioma. Clinical correlation recommended.

Frozen Section Diagnosis:

1. Right parietal lobe brain tumor: Infiltrating glial neoplasm in grey and white matter.

Clinical History and Diagnosis:

Right parietal lobe brain tumor. [REDACTED]

Source of Specimen:

- 1: Right parietal lobe brain tumor
- 2: Specimen not received
- 3: Right parietal lobe brain tumor

Gross Description:

[REDACTED]
[REDACTED]
1. Right parietal lobe brain tumor: Received fresh for frozen section are multiple pieces of soft white tissue measuring 1.3 x 0.8 x 0.3 cm in aggregate. Touch preps are made. 50% of the specimen is submitted for frozen section diagnosis. The remaining specimen is entirely submitted.

2. Specimen not received:

3. Right parietal lobe brain tumor: Received in formalin is a single fragment of tan white soft tissue measuring 0.5 x 0.4 x 0.3 cm. The specimen is bisected and entirely submitted in one cassette.

Histology Laboratory
H&E

Part 3: Right parietal lobe brain tumor

RFCUT

UNSTAINED

[page 3 of 3]
[REDACTED]

[REDACTED] [REDACTED] [REDACTED]

IMMUNOPATHOLOGY REPORT

EVALUATION:

Ki67 (mib-1): positive staining in greater than 10% of tumor cell nuclei in a portion of the tumor (slide 3a) .

grap: positive staining in scattered tumor cells and in reactive astrocytes.

Comment:

See corresponding surgical pathology report [REDACTED]

[REDACTED]

This diagnostic report has been personally interpreted by the signatory
of record.

[REDACTED]

Source: NCI Genomic Data Commons file c7093046-f439-4d45-91ce-c5fa46c7dc47 (TCGA-CS-5390.9162696A-6132-4FE2-B3EE-A13E006225BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).